Somatic mutation profile of tumor specimen 0DMN2D from CCDI case PBCARH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibrillary astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (725 days).
Specimen 0DMN2D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fead248-f371-4dd0-b932-99ba63f201b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN1B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4276209-308b-4468-ba48-c90cd4e3584b

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCNT3 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs559052868, COSV68532018; called by muse, mutect2, varscan2
